Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A43B, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A43B-01A (Primary Tumor).

Procurement Date: Laterality:Tumor Features: Unknown, Tumor Extent: Lesion less than 4.0cm, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Path Report:CERVIX TISSUE CHECKLIST

Specimen type: Simple hysterectomy

Tumor site: Cervix

Tumor size: 2 x 1.5 x 3 cm

Histologic type: Squamous cell carcinoma, keratinizing

Histologic grade: Moderately differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: 0/24 positive for metastasis (Obturator right and left, presacral, paraaortic, 0/24)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

carcinoma, squamous cell, keratinizing
8071/3

Site: Cervix, NOS

C53.9

81312 20

Source: NCI Genomic Data Commons file 56c9541d-edbb-4cc4-9f7d-5d6192169c6f (TCGA-EA-A43B.D2D8553E-1C68-4ADC-9D3E-024D04E948C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).